Somatic mutation profile of tumor specimen TCGA-23-2081-01A (aliquot TCGA-23-2081-01A-01W-0722-08) from TCGA case TCGA-23-2081, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 49.7 years (18,162 days).
Specimen TCGA-23-2081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1022d57-8ef7-43b8-bfea-c7384083c2ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2081-10A (Blood Derived Normal), aliquot TCGA-23-2081-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a139b884-4b67-46ca-9168-e9596825eacd

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Frame Shift Del 4, Nonsense Mutation 4, Frame Shift Ins 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADORA2B | c.944T>G p.V315G | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV58482128; called by muse, mutect2, varscan2
- ANXA13 | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs1359866003, COSV51623299; called by muse, mutect2
- ATF7 | c.1363T>A p.S455T (on ENST00000548446 / NM_001366555.2; = p.S444T on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV100129047; called by muse, mutect2, varscan2
- BCL9L | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); catalogued as rs747301969, COSV52683933; called by mutect2, varscan2
- BIRC2 | c.1635G>A p.M545I | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99926469; called by muse, varscan2
- CACNA1D | c.5264A>C p.N1755T (on ENST00000350061 / NM_001128840.3; = p.N1775T on NM_000720.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as COSV55446961; called by muse, mutect2, varscan2
- CDH23 | c.7660G>T p.E2554* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as CM063888, COSV56449110, COSV56463323; called by muse, mutect2, varscan2
- CDKL5 | c.2755C>A p.P919T | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV66106476; called by muse, mutect2, varscan2
- CNOT11 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV56819830; called by muse, mutect2, varscan2
- CNTN3 | c.2335G>C p.G779R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV55171178; called by muse, mutect2, varscan2
- CYSLTR1 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64820157; called by muse, mutect2, varscan2
- FAM180A | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1253384301, COSV58528462; called by muse, mutect2, varscan2
- FBXW2 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.948); catalogued as COSV100535033; called by muse, mutect2, varscan2
- GTF3C3 | c.1810T>C p.S604P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55832131; called by muse, mutect2, varscan2
- HCFC1 | c.2439A>T p.K813N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60072154; called by mutect2, varscan2
- HCN1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs951258297, COSV57504948, COSV57537040; called by muse, mutect2, varscan2
- HSD3B1 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52490639; called by muse, mutect2, varscan2
- IRS4 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV64533830; called by muse, mutect2, varscan2
- MMUT | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as COSV99222113; called by muse, mutect2, varscan2
- MUC17 | c.392G>C p.S131T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60288409; called by muse, mutect2, varscan2
- NOP16 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as COSV51257629; called by muse, varscan2
- NTAQ1 | c.239A>T p.Y80F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV54874547; called by muse, mutect2, varscan2
- OR10J5 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs373445383, COSV58385891; called by muse, mutect2, varscan2
- OR5A2 | c.790A>T p.S264C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100119626; called by muse, mutect2, varscan2
- OTOP2 | c.1332A>T p.Q444H | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58881896; called by muse, mutect2, varscan2
- PCDHA7 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV65344096; called by muse, mutect2, varscan2
- PXDN | c.2592dup p.N865Qfs*2 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs773978095; called by mutect2, varscan2
- SALL4 | c.1608C>G p.F536L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV53852183; called by muse, mutect2, varscan2
- SLC38A5 | c.1200C>G p.I400M | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58334179; called by muse, mutect2, varscan2
- TMCC3 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54154446; called by muse, mutect2, varscan2
- TMEM132D | c.164A>C p.N55T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV70604758; called by muse, varscan2
- ZNF479 | c.499G>C p.G167R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV100482998, COSV58638391; called by mutect2, varscan2
- ZNF665 | c.177A>T p.R59S (on ENST00000600412; = p.R124S on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV67215096; called by muse, mutect2, varscan2
- ZNF804B | c.2234G>T p.R745I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100301192, COSV60822213; called by muse, mutect2, varscan2
- ZNF821 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100546693; called by muse, mutect2, varscan2
- C1orf146 | c.501_531del p.Q168Tfs*8 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel
- CALCR | c.1287_1336del p.W429Cfs*21 (on ENST00000649521 / NM_001164737.2; = p.W413Cfs*21 on NM_001742.4) | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel
- COL28A1 | c.183_186del p.A62Sfs*12 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- HKDC1 | c.1318_1328del p.V440Pfs*51 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- POC1B | c.1094T>C p.L365P | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.202); called by muse, varscan2
- ATP11B | c.2787T>C p.S929= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV100017416, COSV60030406; called by muse, mutect2, varscan2
- ATRIP | c.2232C>T p.V744= (on ENST00000320211 / NM_130384.3; = p.V717= on NM_032166.4) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs757022430, COSV56496976; called by mutect2, varscan2
- B3GNTL1 | c.126A>G p.Q42= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as rs200476683; called by muse, mutect2, varscan2
- CDH22 | c.1011G>A p.E337= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV64837552; called by muse, mutect2, varscan2
- COL12A1 | c.6330T>C p.N2110= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV59395959; called by muse, mutect2, varscan2
- FCGR3A | c.522G>A p.G174= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV63459592; called by muse, mutect2, varscan2
- FOXA3 | c.792C>T p.G264= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as rs539294853, COSV56215416; called by muse, mutect2, varscan2
- MUC16 | c.6645A>G p.T2215= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV67465578; called by muse, mutect2, varscan2
- NPBWR1 | c.963G>A p.L321= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs758707576, COSV58696173; called by muse, mutect2, varscan2
- OR8G2P | c.54A>G p.S18= | Silent (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- RTF1 | c.1428A>G p.E476= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV67478103; called by muse, varscan2
- TCEAL1 | c.117G>A p.S39= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV65461096; called by muse, mutect2, varscan2
- TJP1 | c.1704G>A p.E568= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV62041929; called by muse, mutect2, varscan2
- TTC17 | c.1659C>T p.S553= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as COSV50008520; called by muse, mutect2, varscan2
- ZNF304 | c.1116T>C p.F372= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs755735227, COSV99988478; called by muse, varscan2
- NXT2 | c.-53G>C | 5'UTR (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99483998; called by muse, varscan2
- RMDN2 | c.453-22108C>A | Intron (SNP) | VAF 39/110 reads (35%) | catalogued as COSV52224992; called by muse, mutect2, varscan2
